Somatic mutation profile of tumor specimen TCGA-AB-2868-03B (aliquot TCGA-AB-2868-03B-01W-0728-08) from TCGA case TCGA-AB-2868, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute megakaryoblastic leukaemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 77.3 years (28,216 days).
Specimen TCGA-AB-2868-03B: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe79c0c8-bcef-4a39-aafe-af6c4f5b56c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2868-11B (Solid Tissue Normal), aliquot TCGA-AB-2868-11B-01W-0729-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/38427266-a7e7-427c-b4f0-3a82ae5d64ff

The open-access MAF lists 16 somatic variants for this specimen: 16 protein-altering or splice-affecting.
By variant classification: Missense Mutation 15, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.376-1G>A p.X126_splice | Splice Site (SNP) | VAF 43/106 reads (41%) | hotspot (GDC flag); catalogued as rs868137297, CS1313555, COSV52688618, COSV52749979, COSV52994579, COSV52996344; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- C1RL | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 102/399 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.102); catalogued as rs1006906956, COSV56925333; called by muse, mutect2, varscan2
- CATSPER4 | c.596C>A p.P199H | Missense Mutation (SNP) | VAF 75/320 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV58793390; called by muse, varscan2
- FOXP2 | c.926C>A p.P309Q | Missense Mutation (SNP) | VAF 23/386 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV100646255; called by muse, mutect2
- LRBA | c.1772A>G p.Y591C | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1321650166, COSV63956418; called by muse, mutect2, varscan2
- LZTS1 | c.574C>G p.Q192E | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV56117029; called by muse, mutect2, varscan2
- PHACTR1 | c.947T>G p.L316R | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60668480; called by muse, mutect2, varscan2
- PIK3CB | c.1232T>A p.V411E | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as COSV56689673; called by muse, mutect2
- RFX4 | c.358G>A p.G120R | Missense Mutation (SNP) | VAF 106/390 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV57576226, COSV57576644, COSV57579808; called by muse, mutect2, varscan2
- SLC25A52 | c.812G>A p.R271Q (on ENST00000672005; = p.R261Q on NM_001034172.4) | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as rs779757745, COSV52502019; called by muse, mutect2, varscan2
- SPEN | c.1949A>C p.Y650S | Missense Mutation (SNP) | VAF 50/218 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV65362807, COSV65366130; called by muse, mutect2, varscan2
- STK33 | c.787G>T p.V263L | Missense Mutation (SNP) | VAF 111/389 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.272); catalogued as COSV59402156; called by muse, mutect2, varscan2
- ZC3H18 | c.1078A>G p.R360G | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.985); catalogued as rs374973909; called by muse, mutect2, varscan2
- ZNF783 | c.659G>A p.R220K | Missense Mutation (SNP) | VAF 40/175 reads (23%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); catalogued as COSV65185518; called by muse, mutect2, varscan2
- ADGRF2 | c.1535T>A p.I512K (on ENST00000296862 / NM_001368115.2; = p.I444K on NM_153839.7) | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.94); PolyPhen benign (0.113); called by muse, mutect2
- TNRC6B | c.2451T>A p.N817K | Missense Mutation (SNP) | VAF 28/458 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.024); called by muse, mutect2
